Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GC, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GC-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Diagnosis:

A: Kidney, right, radical nephrectomy

Tumor histologic type: Renal cell carcinoma, chromophobe type, eosinophilic variant; see comment

Sarcomatoid features: Not identified

Histologic grade: grade 3 of 4 (Fuhrman classification)

Tumor size: 4.5 x 4.2 x 3.5 cm (gross measurement)

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Negative for malignancy, but close; tumor is less than 1 mm from the capsular surface

Gerota's fascia: Not involved

Renal sinus: Not involved

Major veins (renal vein or segmental branches, IVC): Not involved

Ureter: Not involved

Venous (large vessel): Not identified

Lymphatic (small vessel): Not identified

Surgical margins:

Gerota's fascia (nephrectomy): Negative for malignancy

Renal vein (nephrectomy): Negative for malignancy

Ureter (nephrectomy): Negative for malignancy

Adrenal gland: Not received

Lymph nodes: One lymph node, negative for carcinoma (0/1).

Pathologic findings in non-neoplastic kidney: Focal glomerulosclerosis.

AJCC Stage: pT1b pN0

This staging information is based on information available at the time

ICD O-3
Carcinoma, renal cell chromophobe
type 8317/3
Site (R) Kidney NOS C64.9
QW 9/24/13

[page 2 of 3]
of this report, and is subject to change pending clinical review and additional information.

Comment:

Immunostains were performed on block A2 and demonstrate the tumor is positive for CD10 and c-KIT while being negative for CK7, RCC, and vimentin. A Hales colloidal iron shows patchy staining in tumor cells. Overall, these findings are most consistent with the chromophobe type of renal cell carcinoma.

Dr. has reviewed this case and concurs.

Clinical History:

-year-old female with right renal mass.

Gross Description:

Received is one appropriately labeled container:

Specimen fixation: formalin

Type of specimen: radical nephrectomy

Side of specimen: right

Size and weight of specimen: 490.0 grams, 16.0 x 10.0 x 4.0 cm overall
Kidney: 13.0 x 7.5 x 3.0 cm

Orientation: Inking: surface of kidney=blue

Presence/absence of adrenal gland: absent

Tumor site: superior pole; renal cortex

Tumor description: pink/tan, well circumscribed, with a single central cyst with a solid lining, and multiple areas of hemorrhage

Tumor size: 4.5 x 4.2 x 3.5 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined

Extent of invasion:

Perirenal adipose tissue: does not involve

[page 3 of 3]
Gerota' s fascia: does not involve

Renal vein: does not involve

Ureter: does not involve

Renal Sinus: does not involve

Pelvicaliceal: does not involve

Adrenal: not submitted

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: Grossly unremarkable

Hilar lymph nodes: no palpable lymph nodes are identified

Other significant findings: none

Tissue submitted for special investigations: Tumor and normal were harvested by the

Digital picture: none

Block summary:

- A1 - ureter, vein, artery and margins, en face
- A2 - tumor and normal parenchyma, closest blue inked margin
- A3 - tumor and closest renal pelvis
- A4-A5 - tumor expanding capsule, closet blue inked margin
- A6 - closest renal sinus, uninvolved
- A7 - normal kidney
- A8-A9 - representative sections of hilar fat with possible lymph node candidate

H/OPA Discrepancy		✓
Prior Malignancy History breast	✓	

Source: NCI Genomic Data Commons file 09551665-3112-412e-9eef-4a845d2af6e4 (TCGA-UW-A7GC.5C0FC1D3-5FFA-4B43-9C33-32E0E7D5EFCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).